Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A80P, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A80P-01A (Primary Tumor).

ICD-O-3

*Pheochromocytoma, extra-adrenal
indefinite*

869313

Site: Retroperitoneum

9/10/17/13

Clinical data:

Chromatin cells? Extra-adrenal tumour.

Material: 1: lymph node next to pheochromocytoma. II: pheochromocytoma.

Frozen section: a lymph node, free

Macroscopy

I: pink / white soft lymph node, maximum size 2.25 x 1.5 x 1.5 cm.

II received an encapsulated tumor. Size 7 x 5 x 4 cm. On one side adherent muscle and connective tissue. the hairstyle looks intact. The tumor has a multinodular aspect. The tumor cross laminated. It is dabbed, frozen for and taken for . Also material for research Ferric chloride Reaction negative. Then, a three representative sections done in A through C (3b).

Microscopy

I: microscopic examination shows sections through a lymph node (frozen section + paraffin coupe) without tumor localization.

II: Microscopic examination shows in A t / m C bisected by a very cell rich tumor, surrounded by a fibrous capsule. The tumor shows an alveolar pattern construction and the cells show an epithelial character. Between cell nests fine, fibrous septa, which many small vessels. The tumor cells have large, eosinophilic, granular cytoplasm and a round, hypo to hyper chromatic nucleus with a coarse granular, irregular distributed chromatin pattern. The cores possess distinct nucleoli. Many polynuclear cells. Mitoses are found scattered. Brown to black pigment dispersed in the granular cells. Focal necrosis and hemorrhage in the tumor. The tumor shows an expansive growth, focal capsular invasion. In many places fibrosis and sclerosis of intercellular septa and larger areas with remnants of old bleeding and siderophages. In the hairstyle many vessels, nerve fibers and lymphoid tissue. In many places in the tumor thrombosis of vessels.

Assistive technologies:

ELECTRONMICROSCOPY (EM)

Number

Ten fragments intended for EM examination were fixed in glutaraldehyde and embedded in the usual manner. For orientation were three raised. Light microscopical examination of the thin semi-toluidine blue stained shows representative tissue in all the blocks. Block (2) was further processed for EM research.

In all tumor cells examined numerous secretory granula surrounded by a thin membrane. Furthermore, the tumor cells contain many mitochondria. The EM research supports the diagnosis pheochromocytoma.

Immunopathology

Number

The tumor cells show positivity for resp. S100 and NSE, weak diffuse positivity for chromo-graninen and positive vimentin in the septa.

Conclusion:

FINAL CONCLUSION: Extra-adrenal pheochromocytoma with necrotic hearths and focal capsular invasion. No vascular invasion. No adrenal remains found.

EM research: Em research support the diagnosis pheochromocytoma.

Pathologist:

Source: NCI Genomic Data Commons file 2e773056-c7a4-474c-9bee-5b4fecef6927 (TCGA-WB-A80P.AF4A151B-6562-403E-A970-EEB0533AC088.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).